Somatic mutation profile of tumor specimen TARGET-30-PALPGG-01A (aliquot TARGET-30-PALPGG-01A-01W) from TARGET case TARGET-30-PALPGG, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 1.9 years (700 days).
Specimen TARGET-30-PALPGG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cf60e13-3f23-4acc-9720-14181312324b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALPGG-10A (Blood Derived Normal), aliquot TARGET-30-PALPGG-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/906f563b-a625-46d5-8576-cb6083dc82be

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.742C>A p.P248T | Missense Mutation (SNP) | VAF 30/419 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs149688443; ClinVar: benign; called by muse, mutect2
- CACTIN | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as COSV50267250; called by muse, mutect2, varscan2
- COQ9 | c.104G>C p.R35P | Missense Mutation (SNP) | VAF 4/97 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as rs1180958497; called by muse, mutect2
- CYTH3 | c.735C>A p.N245K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV63437633, COSV63437955; called by muse, mutect2, varscan2
- EXTL3 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 33/400 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.825); catalogued as rs368473155; called by muse, mutect2
- POLR1B | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 13/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1169528728, COSV54499492, COSV99637828; called by muse, mutect2
- RBM47 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55931980; called by muse, mutect2, varscan2
- RBM5 | c.2381C>T p.S794L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.154); catalogued as rs1198799823, COSV61736968; called by muse, mutect2, varscan2
- SH3KBP1 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 14/350 reads (4%) | catalogued as COSV101115274; called by muse, mutect2
- TAB3 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 165/539 reads (31%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.713); catalogued as COSV55835386; called by muse, mutect2, varscan2
- TSPOAP1 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567850059, COSV99272952; called by muse, mutect2
- XIRP2 | c.5345C>A p.S1782* (on ENST00000628543; = p.S1957* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 91/379 reads (24%) | catalogued as COSV54689126; called by muse, mutect2, varscan2
- ARIH2 | c.491G>T p.C164F | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GALNT18 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2
- TP63 | c.1871C>A p.S624Y | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- FMO3 | c.1365C>A p.P455= | Silent (SNP) | VAF 13/432 reads (3%) | called by muse, mutect2
- MESP2 | c.1113G>A p.Q371= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV59092282; called by muse, mutect2
- RFX3 | c.144G>A p.Q48= | Silent (SNP) | VAF 221/641 reads (34%) | catalogued as COSV56508376; called by muse, mutect2, varscan2
- ZNF658B | n.1064G>T | RNA (SNP) | VAF 32/736 reads (4%) | called by muse, mutect2
